TCGA case TCGA-D1-A167 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Mayo Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3d215e20-9eea-47e0-849e-cff1fee5634d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 70.0 years (25,575 days); Year of diagnosis: 2008; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IC; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 478 days (1.3 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 52.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 20.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 60.
   Treatment given: Treatment type: Radiation, Implants; Treatment intent type: Adjuvant; Days to treatment start: 138 days; Days to treatment end: 146 days; Treatment dose: 2,100 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (2 entries)
- Days to follow up: 478 days (1.3 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 152 cm; BMI: 31.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D1-A167-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 140 mg.
  Slide TCGA-D1-A167-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 15; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample TCGA-D1-A167-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D1-A167-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Surgical approach at diagnosis: open.
- Follow-up form: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; History tamoxifen use: Never Used; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 2; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 478 days; disease-specific survival: no event (censored), 478 days; disease-free interval: no event (censored), 478 days; progression-free interval: no event (censored), 478 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D1-A167-01A-11D-A12G-01): tumor purity 0.91, ploidy 2, whole-genome doublings 0.
